Somatic mutation profile of tumor specimen ALCH-AC12-TTP1-A (aliquot ALCH-AC12-TTP1-A-1-0-D-A49D-36) from ALCHEMIST case ALCH-AC12, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,942 days).
Specimen ALCH-AC12-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c45268f-66d9-4aa9-b2d2-158277f7c220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC12-NB1-A (Blood Derived Normal), aliquot ALCH-AC12-NB1-A-1-0-D-A49D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f29bed-23e8-4a7f-bbac-df780788cd80

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 4, Translation Start Site 2, 3'Flank 2, 3'UTR 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 22/347 reads (6%) | hotspot (GDC flag); catalogued as COSV58684005, COSV58689871; called by muse, mutect2
- KCNB1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 65/282 reads (23%) | catalogued as rs1064794764, COSV65567531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 42/211 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UNC13D | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 18/394 reads (5%) | catalogued as rs1274685768, CM081468, COSV52882834; ClinVar: likely pathogenic; called by muse, mutect2
- C7orf33 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 146/753 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1176681066; called by muse, mutect2, varscan2
- CACNA1B | c.5931G>A p.M1977I | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs375356285; called by muse, mutect2, varscan2
- CNTNAP2 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 39/1212 reads (3%) | catalogued as rs771533907, COSV100662227; called by muse, mutect2
- CSRNP1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746438028, COSV99827212; called by muse, mutect2
- DENND1C | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs890654727, COSV57567978; called by muse, mutect2
- FERMT1 | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54096082; called by muse, mutect2, varscan2
- FTSJ3 | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376996404; called by muse, mutect2
- NT5E | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 36/884 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57630573; called by muse, mutect2
- PDZD2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1348523938, COSV56851245; called by muse, mutect2
- PMFBP1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 78/563 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1188457733, COSV52824078; called by muse, mutect2, varscan2
- SLC29A4 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991980673, COSV51873338; called by muse, mutect2, varscan2
- USP17L4 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 107/815 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs768218594; called by muse, mutect2, varscan2
- ACACA | c.2932-2A>G p.X978_splice | Splice Site (SNP) | VAF 30/1045 reads (3%) | called by muse, mutect2
- AKAP9 | c.530_531del p.E177Afs*11 | Frame Shift Del (DEL) | VAF 142/1009 reads (14%) | called by pindel, varscan2
- ASNSD1 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 14/421 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- BTBD18 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- CEP295 | c.3611C>G p.T1204S | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHERP | c.2103G>C p.R701S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DST | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- FDPS | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- GGA2 | c.1006+1G>T p.X336_splice | Splice Site (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- GPR39 | c.121T>G p.F41V | Missense Mutation (SNP) | VAF 37/1238 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- IL17RB | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 101/781 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KATNIP | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 28/797 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.065); called by muse, mutect2
- LAMA1 | c.3652T>G p.Y1218D | Missense Mutation (SNP) | VAF 52/631 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LGALS12 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- MAP1A | c.3300T>A p.F1100L | Missense Mutation (SNP) | VAF 63/486 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K3 | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OSBP | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SREBF2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 20/698 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.091); called by muse, mutect2
- TAF6 | c.1084-7C>T | Splice Region (SNP) | VAF 82/391 reads (21%) | called by muse, mutect2, varscan2
- WDFY3 | c.8798A>T p.H2933L | Missense Mutation (SNP) | VAF 32/959 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF728 | c.915T>G p.I305M | Missense Mutation (SNP) | VAF 24/576 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- ADAMTSL3 | c.3075T>C p.S1025= | Silent (SNP) | VAF 33/556 reads (6%) | called by muse, mutect2
- AUTS2 | c.897C>T p.C299= | Silent (SNP) | VAF 102/1024 reads (10%) | called by muse, mutect2, varscan2
- GTSF1 | c.399G>A p.A133= | Silent (SNP) | VAF 24/367 reads (7%) | catalogued as rs764553625; called by muse, mutect2
- LCT | c.5736G>A p.G1912= | Silent (SNP) | VAF 70/958 reads (7%) | catalogued as COSV51556461; called by muse, mutect2
- OR5M11 | c.459A>G p.S153= | Silent (SNP) | VAF 64/511 reads (13%) | catalogued as COSV101602081; called by muse, mutect2, varscan2
- PIGS | c.552C>A p.R184= | Silent (SNP) | VAF 88/551 reads (16%) | called by muse, mutect2, varscan2
- SCN5A | c.1050C>T p.H350= | Silent (SNP) | VAF 29/223 reads (13%) | catalogued as rs587781160, COSV100348612; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- SKIV2L | c.2748C>A p.T916= | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- TENT5A | c.418C>T p.L140= | Silent (SNP) | VAF 84/464 reads (18%) | catalogued as rs779013313; called by muse, mutect2, varscan2
- FMR1 | c.*1309C>G | 3'UTR (SNP) | VAF 12/169 reads (7%) | catalogued as COSV99503754; called by muse, mutect2
- GATM | c.*37A>C | 3'UTR (SNP) | VAF 87/632 reads (14%) | called by muse, mutect2, varscan2
- GH2 | c.457-69G>A | Intron (SNP) | VAF 22/663 reads (3%) | called by muse, mutect2
- R3HDML | chr20:44355708 G>C | 3'Flank (SNP) | VAF 16/469 reads (3%) | called by muse, mutect2
- TRAC | chr14:22557093 C>T | 3'Flank (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
